Somatic mutation profile of tumor specimen ALCH-B4C9-TTP1-A (aliquot ALCH-B4C9-TTP1-A-5-0-D-A80E-36) from ALCHEMIST case ALCH-B4C9, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 57.3 years (20,915 days).
Specimen ALCH-B4C9-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bba095a6-9b0c-4cbd-b431-6bbd8409a1c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4C9-NB1-A (Blood Derived Normal), aliquot ALCH-B4C9-NB1-A-1-0-D-A80E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/91811d61-73a5-45fd-b593-b7dbb344726c

The open-access MAF lists 24 somatic variants for this specimen: 16 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 7, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRB3 | c.3308G>C p.C1103S | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53235279; called by muse, mutect2, varscan2
- AL136295.1 | c.1426C>T p.R476W | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774945508; called by mutect2, varscan2
- BCOR | c.3754A>G p.I1252V (on ENST00000378444 / NM_001123385.2; = p.I1218V on NM_017745.6) | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT tolerated (0.77); PolyPhen benign (0.005); catalogued as COSV60715405; called by muse, mutect2
- NRG3 | c.1081G>A p.V361M | Missense Mutation (SNP) | VAF 26/331 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV64544359; called by muse, mutect2
- PYGL | c.809G>A p.R270Q | Missense Mutation (SNP) | VAF 315/843 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.745); catalogued as rs755488866, COSV53588634; called by muse, mutect2, varscan2
- SORT1 | c.520A>G p.I174V | Missense Mutation (SNP) | VAF 26/410 reads (6%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs751887405; called by muse, mutect2
- ACACA | c.6631T>G p.F2211V | Missense Mutation (SNP) | VAF 38/440 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.02); called by muse, mutect2
- ARMCX5 | c.1454A>G p.N485S | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- COL11A1 | c.5353A>G p.I1785V | Missense Mutation (SNP) | VAF 38/486 reads (8%) | SIFT tolerated (0.69); PolyPhen benign (0.007); called by muse, mutect2
- CYTH3 | c.619C>A p.H207N | Missense Mutation (SNP) | VAF 14/288 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.017); called by muse, mutect2
- DDIAS | c.1247T>A p.L416Q | Missense Mutation (SNP) | VAF 20/215 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- MUC4 | c.1718C>A p.T573N | Missense Mutation (SNP) | VAF 20/193 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.413); called by muse, mutect2
- OR4A47 | c.257G>C p.G86A | Missense Mutation (SNP) | VAF 18/366 reads (5%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.014); called by muse, mutect2
- RAI1 | c.473C>G p.A158G | Missense Mutation (SNP) | VAF 24/402 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.023); called by muse, mutect2
- SLC9A3 | c.1431G>C p.E477D | Missense Mutation (SNP) | VAF 21/262 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2
- SLC9A3 | c.1063G>A p.G355S | Missense Mutation (SNP) | VAF 14/246 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.321); called by muse, mutect2
- ASXL2 | c.945T>C p.G315= | Silent (SNP) | VAF 8/132 reads (6%) | called by muse, mutect2
- ATP5PO | c.480C>A p.V160= | Silent (SNP) | VAF 45/322 reads (14%) | called by muse, mutect2, varscan2
- CNTN2 | c.1086G>C p.R362= | Silent (SNP) | VAF 8/126 reads (6%) | called by muse, mutect2
- DNAH5 | c.6213G>A p.V2071= | Silent (SNP) | VAF 293/574 reads (51%) | called by muse, mutect2, varscan2
- NKAIN4 | c.210C>G p.A70= | Silent (SNP) | VAF 26/250 reads (10%) | called by muse, mutect2
- RNF123 | c.2730C>T p.D910= | Silent (SNP) | VAF 19/229 reads (8%) | catalogued as rs754283760; called by muse, mutect2
- SLC9A3 | c.1290G>A p.K430= | Silent (SNP) | VAF 31/491 reads (6%) | called by muse, mutect2
- ATL1 | c.-7G>T | 5'UTR (SNP) | VAF 20/354 reads (6%) | called by muse, mutect2
